Gene-level copy-number profile of tumor specimen C3N-00661-01 from CPTAC case C3N-00661, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.4 years (18,038 days).
Specimen C3N-00661-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 96807350-e785-4097-8081-b83151f2f0c4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00661-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/bedc7a7e-761d-43a6-b3b6-e5249811f0cf

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 38; copy number 2: 5,574; copy number 3: 1,163; copy number 4: 45,358; copy number 5: 894; copy number 6: 5,771; copy number 7: 3; copy number 9: 5; copy number 10: 2; copy number 12: 5; copy number 13: 7; copy number 94: 3; copy number 101: 13; copy number 102: 2; copy number 104: 25; copy number 105: 5; copy number 211: 9; copy number 222: 4; copy number 251: 9; copy number 262: 11; copy number 362: 4; copy number 363: 1; copy number 521: 6.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 111 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:57,475,445–57,959,148, 40 genes, copy number 12–251 (within-gene range 2–251): MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG.
- chr12:62,260,338–62,417,431, 3 genes, copy number 94 (within-gene range 2–94): USP15, MIR6125, RNU6-595P.
- chr12:62,466,817–62,600,476, 1 gene, copy number 101 (within-gene range 4–101): MON2.
- chr12:62,545,582–62,622,213, 5 genes, copy number 101: RNU6-399P, LINC01465, AC048341.1, MIRLET7I, AC048341.2.
- chr12:64,186,316–64,451,125, 9 genes, copy number 101–102 (within-gene range 4–102): C12orf66, RNU6-1009P, AC012158.1, RNU5A-7P, C12orf56, OOEPP2, ATP6V1E1P3, AC135279.1, XPOT.
- chr12:65,645,992–66,066,338, 10 genes, copy number 12–211: PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362.
- chr12:68,686,951–68,745,809, 1 gene, copy number 9 (within-gene range 2–9): NUP107.
- chr12:68,746,125–70,443,923, 40 genes, copy number 9–521: SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P.
- chr12:71,839,707–71,927,248, 1 gene, copy number 10 (within-gene range 5–10): TBC1D15.
- chr19:55,262,223–55,280,381, 1 gene, copy number 10: HSPBP1.

Autosomal genes at a single copy (total copy number 1): 27. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
